Surgical pathology report (de-identified scan), TCGA case TCGA-S9-A6TW, project TCGA-LGG (Brain Lower Grade Glioma), tissue source site Dept of Neurosurgery at University of Heidelberg, specimen TCGA-S9-A6TW-01A (Primary Tumor).

Histomorphology shows oligodendroglial differentiation. Mitotic activity present.
Proliferation focally 20%.

Diagnosis

Anaplastic oligodendroglioma WHO grade III

CKF ICD-3

Oligodendroglioma, grade III
9451/3

path
Oligodendroglioma, anaplastic
9451/3

Site: Brain, supratentorial
C71.0

7/25/13

Untranslated original report
is housed at the BCR

Source: NCI Genomic Data Commons file 4278d162-8607-453b-a3ae-cb751c906323 (TCGA-S9-A6TW.D13F9A44-42C4-4DC2-A8EB-9E7CFBF7511D.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).